Somatic mutation profile of tumor specimen 0DRIWB from CCDI case PBCGPJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 14.0 years (5,129 days).
Specimen 0DRIWB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb7b7b9e-426d-4cc5-9a4e-0540d2330612.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRIWK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/900a5599-9955-4744-a4c1-b359ce2a9615

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Intron 4, Nonsense Mutation 3, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMHR2 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 196/951 reads (21%) | catalogued as rs769617823, COSV57684803, COSV57685504; called by muse, mutect2, varscan2
- BDP1 | c.2842A>G p.K948E | Missense Mutation (SNP) | VAF 250/1208 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.067); catalogued as rs191158396; called by muse, mutect2, varscan2
- CPPED1 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 102/477 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55498555; called by muse, mutect2, varscan2
- IGSF9 | c.2387G>A p.G796D (on ENST00000368094 / NM_001135050.2; = p.G780D on NM_020789.4) | Missense Mutation (SNP) | VAF 124/658 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1482777831, COSV100231047; called by muse, mutect2, varscan2
- TAT | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 119/658 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV63533129; called by muse, mutect2, varscan2
- TRAF7 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 114/599 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.894); catalogued as COSV58216140; called by muse, mutect2, varscan2
- ACP5 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 451/1037 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- APBA3 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 128/713 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C17orf58 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 72/513 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DNHD1 | c.7387+2T>C p.X2463_splice | Splice Site (SNP) | VAF 133/756 reads (18%) | called by muse, mutect2, varscan2
- DOCK6 | c.4713C>A p.H1571Q | Missense Mutation (SNP) | VAF 42/859 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2
- FFAR4 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 86/608 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT13 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 271/1349 reads (20%) | called by muse, mutect2, varscan2
- GCNT1 | c.1079del p.E360Gfs*29 | Frame Shift Del (DEL) | VAF 236/1022 reads (23%) | called by mutect2, varscan2
- KDM6A | c.3904_3907dup p.C1303Sfs*31 | Frame Shift Ins (INS) | VAF 258/656 reads (39%) | called by mutect2, varscan2
- KIF4B | c.2729C>A p.S910Y | Missense Mutation (SNP) | VAF 49/1781 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2
- KMT2C | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 127/678 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGAM2 | c.4797dup p.T1600Dfs*24 | Frame Shift Ins (INS) | VAF 219/996 reads (22%) | called by mutect2, varscan2
- MYORG | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 158/708 reads (22%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.709C>G p.H237D | Missense Mutation (SNP) | VAF 211/1078 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PSTK | c.812A>G p.N271S | Missense Mutation (SNP) | VAF 234/1313 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TGFBR3 | c.1501C>G p.P501A | Missense Mutation (SNP) | VAF 139/914 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- UPK3A | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 202/1071 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ZNF330 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 404/968 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAD1 | c.1296G>A p.K432= | Silent (SNP) | VAF 233/993 reads (23%) | called by muse, mutect2, varscan2
- KCTD1 | c.735A>T p.V245= | Silent (SNP) | VAF 238/1112 reads (21%) | catalogued as COSV58685547; called by muse, mutect2, varscan2
- PACS2 | c.249C>G p.P83= | Silent (SNP) | VAF 70/524 reads (13%) | catalogued as rs972708233; called by muse, mutect2, varscan2
- PIK3C2A | c.1815A>G p.R605= | Silent (SNP) | VAF 207/1005 reads (21%) | called by muse, mutect2, varscan2
- PRSS57 | c.708C>A p.G236= | Silent (SNP) | VAF 34/944 reads (4%) | called by muse, mutect2
- CDH13 | c.45+12273G>C | Intron (SNP) | VAF 195/1089 reads (18%) | called by muse, mutect2, varscan2
- DDX18 | c.1521+73C>T | Intron (SNP) | VAF 97/399 reads (24%) | catalogued as rs1233045209, COSV54306069; called by muse, mutect2, varscan2
- IGSF9 | c.1362+50G>T | Intron (SNP) | VAF 65/331 reads (20%) | called by muse, mutect2, varscan2
- ISCU | c.115-113G>A | Intron (SNP) | VAF 161/819 reads (20%) | called by muse, mutect2, varscan2
- RNF227 | c.*50G>A | 3'UTR (SNP) | VAF 123/346 reads (36%) | called by muse, mutect2, varscan2
- SSPOP | n.960G>T | RNA (SNP) | VAF 217/896 reads (24%) | called by muse, mutect2, varscan2
